Somatic mutation profile of tumor specimen C3N-00154-04 (aliquot CPT0081880006) from CPTAC case C3N-00154, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 68.8 years (25,116 days).
Specimen C3N-00154-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c7b5b4a0-1bd7-4139-b03f-15ff3a4e5637.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00154-31 (Blood Derived Normal), aliquot CPT0085300002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d4b88d1-bda6-4eba-9255-5b1394a8a46d

The open-access MAF lists 134 somatic variants for this specimen: 93 protein-altering or splice-affecting, 24 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 24, Frame Shift Del 10, 3'UTR 8, Nonsense Mutation 7, Splice Region 3, Intron 3, RNA 2, 5'UTR 2, Splice Site 1, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMAD4 | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 49/186 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61685209, COSV61685537, COSV61689602; called by muse, mutect2, varscan2
- AKNAD1 | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs751500049, COSV62197104; called by muse, varscan2
- ANKLE2 | c.1419G>A p.K473= | Splice Region (SNP) | VAF 15/71 reads (21%) | catalogued as COSV100514269; called by muse, mutect2, varscan2
- AP4E1 | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.689); catalogued as rs768086723, COSV55915344; called by muse, mutect2, varscan2
- CAND1 | c.2900T>G p.L967R | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101607323; called by muse, mutect2, varscan2
- CCDC163 | c.252G>C p.Q84H | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.568); catalogued as rs1415498267; called by muse, mutect2
- CLCA2 | c.466G>A p.G156R | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761212004, COSV100991485; called by muse, mutect2, varscan2
- CRB1 | c.1909C>A p.P637T | Missense Mutation (SNP) | VAF 66/562 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66332730; called by muse, mutect2, varscan2
- DUOX1 | c.1346G>A p.R449H | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs149693969; called by muse, mutect2, varscan2
- EFCAB8 | c.2437C>T p.R813C | Missense Mutation (SNP) | VAF 40/179 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.19); catalogued as rs1439173333, COSV71371333; called by muse, mutect2, varscan2
- ELMOD2 | c.759C>A p.D253E | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100063101; called by muse, mutect2
- FAM13A | c.1112G>C p.R371P | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV51997530; called by muse, varscan2
- FLNA | c.7943G>C p.*2648Sext*81 (on ENST00000369850 / NM_001110556.2; = p.*2640Sext*81 on NM_001456.3) | Nonstop Mutation (SNP) | VAF 10/36 reads (28%) | catalogued as COSV61036883; called by muse, mutect2
- GFUS | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.495); catalogued as rs1056240187; called by muse, mutect2, varscan2
- HDAC6 | c.3532G>C p.D1178H | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100491256; called by muse, mutect2, varscan2
- IGKV4-1 | c.94G>C p.A32P | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.123); catalogued as rs148071875; called by muse, mutect2, varscan2
- KLHL17 | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 47/231 reads (20%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.93); catalogued as rs1359813532, COSV58531443; called by muse, mutect2, varscan2
- LRRC52 | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 32/413 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as rs764714371; called by muse, mutect2
- MTOR | c.4298T>C p.L1433S | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV63868399; called by muse, mutect2, varscan2
- NKTR | c.3329A>G p.H1110R | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs759638816; called by muse, mutect2, varscan2
- NLRP9 | c.206G>A p.W69* | Nonsense Mutation (SNP) | VAF 81/401 reads (20%) | catalogued as COSV60460821; called by muse, mutect2, varscan2
- OR52R1 | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 34/204 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs139182026; called by muse, mutect2, varscan2
- PCDHB6 | c.16G>A p.V6I | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs782287939; called by muse, varscan2
- PCDHGA12 | c.1438G>A p.D480N | Missense Mutation (SNP) | VAF 50/238 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs776132438, COSV99342958; called by muse, mutect2, varscan2
- PRIMA1 | c.123C>A p.C41* | Nonsense Mutation (SNP) | VAF 45/151 reads (30%) | catalogued as COSV60263549; called by muse, mutect2, varscan2
- RGS22 | c.1042A>G p.I348V | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376054141; called by muse, mutect2, varscan2
- SRRM4 | c.1658G>A p.R553Q | Missense Mutation (SNP) | VAF 55/378 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs760836379; called by muse, mutect2, varscan2
- TNFRSF13B | c.103C>A p.P35T | Missense Mutation (SNP) | VAF 114/519 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.938); catalogued as rs753500225; called by muse, mutect2, varscan2
- TRPM3 | c.673G>T p.V225F (on ENST00000357533 / NM_001366142.2; = p.V70F on NM_020952.6) | Missense Mutation (SNP) | VAF 43/214 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as rs1020949356; called by muse, mutect2, varscan2
- USO1 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.104); catalogued as rs973827414; called by muse, mutect2, varscan2
- ZNF16 | c.400G>A p.G134R | Missense Mutation (SNP) | VAF 36/232 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV52765384; called by muse, mutect2, varscan2
- ZNF614 | c.1087C>T p.R363* | Nonsense Mutation (SNP) | VAF 53/239 reads (22%) | catalogued as rs757156365; called by muse, mutect2, varscan2
- ACOX2 | c.1158C>A p.L386= | Splice Region (SNP) | VAF 10/59 reads (17%) | called by muse, mutect2, varscan2
- ACSL5 | c.497del p.L166Wfs*18 (on ENST00000354273; = p.L222Wfs*18 on NM_016234.3) | Frame Shift Del (DEL) | VAF 18/196 reads (9%) | called by mutect2, pindel
- ADNP | c.2197G>C p.D733H | Missense Mutation (SNP) | VAF 43/230 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- AGBL5 | c.190G>C p.E64Q | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.379); called by muse, mutect2
- CACNA1G | c.5224del p.Q1742Rfs*52 | Frame Shift Del (DEL) | VAF 9/86 reads (10%) | called by mutect2, pindel, varscan2
- CALCOCO2 | c.722A>C p.E241A | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- CD4 | c.173del p.Q58Rfs*2 | Frame Shift Del (DEL) | VAF 22/137 reads (16%) | called by mutect2, pindel, varscan2
- CDIPT | c.399C>G p.I133M | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- CGN | c.2805C>G p.D935E | Missense Mutation (SNP) | VAF 36/210 reads (17%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHUK | c.2177A>G p.E726G | Missense Mutation (SNP) | VAF 60/302 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- CLUAP1 | c.77A>C p.N26T | Missense Mutation (SNP) | VAF 37/204 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- CUL3 | c.175A>G p.R59G | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- DGKZ | c.2717T>C p.F906S (on ENST00000454345 / NM_001105540.2; = p.F718S on NM_003646.4) | Missense Mutation (SNP) | VAF 12/259 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- DHX29 | c.2024T>A p.L675* | Nonsense Mutation (SNP) | VAF 11/85 reads (13%) | called by muse, mutect2, varscan2
- DLGAP3 | c.2512G>T p.G838C | Missense Mutation (SNP) | VAF 62/414 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAI4 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 27/203 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- DRICH1 | c.543_544del p.C182Ffs*2 | Frame Shift Del (DEL) | VAF 17/133 reads (13%) | called by mutect2, pindel
- DYNC2LI1 | c.507+3G>T | Splice Region (SNP) | VAF 46/177 reads (26%) | called by muse, mutect2, varscan2
- FAM117B | c.1433A>G p.K478R | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- FKBP14 | c.11del p.F4Sfs*7 | Frame Shift Del (DEL) | VAF 27/85 reads (32%) | called by mutect2, pindel, varscan2
- FLG | c.10141G>A p.G3381R | Missense Mutation (SNP) | VAF 131/681 reads (19%) | SIFT tolerated (0.43); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FMNL2 | c.1517C>T p.S506L | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR139 | c.226G>T p.V76F | Missense Mutation (SNP) | VAF 33/169 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- H2AC20 | c.80C>A p.P27Q | Missense Mutation (SNP) | VAF 59/396 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HCN2 | c.1432G>C p.E478Q | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.115); called by muse, mutect2
- HERC2 | c.6095G>C p.S2032T | Missense Mutation (SNP) | VAF 41/412 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ITLN2 | c.638A>T p.N213I | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ITPKB | c.422T>C p.V141A | Missense Mutation (SNP) | VAF 53/304 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- L1CAM | c.3458T>A p.V1153E | Missense Mutation (SNP) | VAF 70/223 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LARP1B | c.43-4_50delinsTTTTTTTTTTTT p.X15_splice | Splice Site (ONP) | VAF 4/48 reads (8%) | called by mutect2*, pindel
- LIF | c.346del p.L116Wfs*51 | Frame Shift Del (DEL) | VAF 72/685 reads (11%) | called by mutect2, pindel
- LRRC72 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 37/199 reads (19%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- LSM14B | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MRPS28 | c.326A>C p.E109A | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- MTMR11 | c.271C>G p.P91A (on ENST00000439741 / NM_001145862.2; = p.P19A on NM_181873.3) | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- MUC16 | c.22661G>T p.S7554I | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- NAPB | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.272); called by muse, mutect2
- NDUFAF1 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 59/425 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- NEGR1 | c.109A>G p.S37G | Missense Mutation (SNP) | VAF 31/201 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRC5 | c.3196G>T p.D1066Y | Missense Mutation (SNP) | VAF 59/287 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- OPA1 | c.1388C>G p.S463* (on ENST00000361510 / NM_130837.3; = p.S408* on NM_015560.3) | Nonsense Mutation (SNP) | VAF 40/276 reads (14%) | called by muse, mutect2, varscan2
- PARG | c.2908T>G p.S970A | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- PARP1 | c.164C>A p.S55Y | Missense Mutation (SNP) | VAF 55/340 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- PBRM1 | c.2972_2973del p.K991Mfs*12 | Frame Shift Del (DEL) | VAF 23/105 reads (22%) | called by mutect2, pindel
- PGBD1 | c.1651G>T p.E551* | Nonsense Mutation (SNP) | VAF 34/206 reads (17%) | called by muse, mutect2, varscan2
- RAB43 | c.202A>C p.K68Q | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- RAPGEF1 | c.6C>G p.D2E | Missense Mutation (SNP) | VAF 35/207 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- SH2B1 | c.1075G>C p.V359L | Missense Mutation (SNP) | VAF 48/274 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SYCP2L | c.404_411del p.L135Rfs*7 | Frame Shift Del (DEL) | VAF 20/178 reads (11%) | called by mutect2, pindel
- SYT5 | c.235C>T p.Q79* | Nonsense Mutation (SNP) | VAF 25/107 reads (23%) | called by muse, mutect2, varscan2
- THBS1 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 31/227 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TIGD5 | c.195C>G p.I65M | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- TM9SF2 | c.1061A>T p.D354V | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TRABD2A | c.1139A>T p.K380I (on ENST00000409520 / NM_001277053.2; = p.K331I on NM_001080824.3) | Missense Mutation (SNP) | VAF 87/310 reads (28%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- VHL | c.369del p.T124Hfs*35 | Frame Shift Del (DEL) | VAF 177/515 reads (34%) | called by mutect2, pindel, varscan2
- WDR33 | c.4007_4008del p.R1336Lfs*16 | Frame Shift Del (DEL) | VAF 15/48 reads (31%) | called by mutect2, pindel, varscan2
- WLS | c.378C>G p.I126M | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- WWC1 | c.2860A>C p.K954Q | Missense Mutation (SNP) | VAF 40/232 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- ZACN | c.980G>C p.S327T | Missense Mutation (SNP) | VAF 33/198 reads (17%) | SIFT tolerated (0.74); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ZNF235 | c.2013T>G p.S671R | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ZNF716 | c.424T>A p.Y142N | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- ANAPC7 | c.678G>A p.V226= | Silent (SNP) | VAF 25/185 reads (14%) | called by muse, mutect2, varscan2
- ATP5ME | c.198C>T p.S66= | Silent (SNP) | VAF 47/208 reads (23%) | catalogued as COSV99727505; called by muse, mutect2, varscan2
- BHMG1 | c.630C>G p.S210= | Silent (SNP) | VAF 59/302 reads (20%) | called by muse, mutect2, varscan2
- C19orf47 | c.618G>A p.E206= | Silent (SNP) | VAF 46/230 reads (20%) | called by muse, mutect2, varscan2
- CD33 | c.309G>C p.L103= | Silent (SNP) | VAF 16/90 reads (18%) | called by muse, mutect2, varscan2
- CRYBG2 | c.4269C>G p.G1423= | Silent (SNP) | VAF 9/147 reads (6%) | called by muse, mutect2
- FAM222B | c.624G>A p.L208= | Silent (SNP) | VAF 27/127 reads (21%) | called by muse, mutect2, varscan2
- GRM3 | c.1618C>T p.L540= | Silent (SNP) | VAF 74/313 reads (24%) | called by muse, mutect2, varscan2
- HOXC5 | c.384C>T p.P128= | Silent (SNP) | VAF 14/114 reads (12%) | called by muse, mutect2, varscan2
- KCNJ12 | c.501C>A p.I167= | Silent (SNP) | VAF 16/189 reads (8%) | catalogued as COSV59165887; called by muse, mutect2
- LMTK2 | c.3288C>T p.S1096= | Silent (SNP) | VAF 45/376 reads (12%) | called by muse, mutect2, varscan2
- LTBP4 | c.462C>G p.P154= (on ENST00000308370 / NM_001042544.1; = p.P117= on NM_003573.2) | Silent (SNP) | VAF 16/87 reads (18%) | called by muse, mutect2, varscan2
- MPP7 | c.1242T>C p.G414= | Silent (SNP) | VAF 16/175 reads (9%) | catalogued as COSV61732056; called by muse, mutect2
- NGFR | c.534C>T p.R178= | Silent (SNP) | VAF 14/106 reads (13%) | catalogued as rs768597889, COSV50803210; called by muse, mutect2, varscan2
- PEG3 | c.2871T>C p.F957= | Silent (SNP) | VAF 24/87 reads (28%) | catalogued as rs1441434461; called by muse, mutect2, varscan2
- PFN4 | c.144G>A p.L48= | Silent (SNP) | VAF 47/168 reads (28%) | called by muse, mutect2, varscan2
- PRAMEF4 | c.390C>T p.A130= | Silent (SNP) | VAF 66/381 reads (17%) | catalogued as rs763372024; called by muse, mutect2, varscan2
- SLIT2 | c.2448T>A p.I816= | Silent (SNP) | VAF 13/104 reads (13%) | called by muse, mutect2, varscan2
- SVEP1 | c.8190T>C p.F2730= | Silent (SNP) | VAF 59/307 reads (19%) | called by muse, mutect2, varscan2
- TBC1D24 | c.1074C>G p.P358= (on ENST00000646147 / NM_001199107.2; = p.P352= on NM_020705.3) | Silent (SNP) | VAF 49/232 reads (21%) | called by muse, mutect2, varscan2
- TENM2 | c.1584G>C p.R528= (on ENST00000518659 / NM_001122679.2; = p.R296= on NM_001080428.3) | Silent (SNP) | VAF 53/257 reads (21%) | called by muse, mutect2, varscan2
- TRMT2B | c.1281C>T p.A427= | Silent (SNP) | VAF 32/83 reads (39%) | catalogued as rs757906963, COSV58618881; called by muse, mutect2, varscan2
- ZACN | c.981C>T p.S327= | Silent (SNP) | VAF 35/195 reads (18%) | catalogued as rs564705824, COSV100135297; called by muse, mutect2, varscan2
- ZNF230 | c.732A>G p.K244= | Silent (SNP) | VAF 50/312 reads (16%) | called by muse, mutect2, varscan2
- BRCA1 | c.*296T>G | 3'UTR (SNP) | VAF 18/149 reads (12%) | called by muse, mutect2, varscan2
- C17orf49 | c.-11C>T | 5'UTR (SNP) | VAF 49/255 reads (19%) | catalogued as rs1282077349; called by muse, mutect2, varscan2
- CFL2 | c.*633C>G | 3'UTR (SNP) | VAF 18/181 reads (10%) | called by muse, mutect2
- CHRNA4 | c.*305G>A | 3'UTR (SNP) | VAF 97/574 reads (17%) | called by muse, mutect2, varscan2
- FLRT2 | chr14:85528732 C>G | 5'Flank (SNP) | VAF 30/169 reads (18%) | called by muse, mutect2, varscan2
- GAB3 | c.1645-753G>A | Intron (SNP) | VAF 8/22 reads (36%) | called by muse, varscan2
- HEXD | c.*21G>A | 3'UTR (SNP) | VAF 19/151 reads (13%) | called by muse, mutect2, varscan2
- IGSF22 | c.*853G>A | 3'UTR (SNP) | VAF 27/190 reads (14%) | called by muse, mutect2, varscan2
- MPRIP | c.2164-4268G>T | Intron (SNP) | VAF 63/342 reads (18%) | catalogued as rs1431813012; called by muse, mutect2, varscan2
- NUDC | c.*25C>G | 3'UTR (SNP) | VAF 54/285 reads (19%) | called by muse, mutect2, varscan2
- PPP4R1L | n.1152A>T | RNA (SNP) | VAF 58/348 reads (17%) | called by muse, mutect2, varscan2
- PTPRD | c.*7C>T | 3'UTR (SNP) | VAF 72/169 reads (43%) | called by muse, mutect2, varscan2
- RPS26P15 | n.311C>T | RNA (SNP) | VAF 44/226 reads (19%) | catalogued as rs780499684; called by muse, mutect2, varscan2
- SLC25A27 | c.-2G>C | 5'UTR (SNP) | VAF 16/162 reads (10%) | called by muse, mutect2
- SNORD50B | chr6:85677340 T>G | 3'Flank (SNP) | VAF 8/125 reads (6%) | called by muse, mutect2
- TACC2 | c.*72T>G | 3'UTR (SNP) | VAF 14/96 reads (15%) | called by muse, mutect2, varscan2
- ZFP28 | c.898+31C>G | Intron (SNP) | VAF 64/412 reads (16%) | catalogued as COSV100019841; called by muse, varscan2
